Somatic mutation profile of tumor specimen TCGA-VQ-AA6K-01A (aliquot TCGA-VQ-AA6K-01A-11D-A410-08) from TCGA case TCGA-VQ-AA6K, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.0 years (21,901 days).
Specimen TCGA-VQ-AA6K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65499add-e323-4f6e-8b8d-0266783c26f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6K-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6K-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe1d6519-dec5-472f-a5d9-f42e8c541d10

The open-access MAF lists 73 somatic variants for this specimen: 60 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Nonsense Mutation 6, Frame Shift Ins 3, Frame Shift Del 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2329A>G p.I777V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1337064915, COSV66064004; called by muse, mutect2, varscan2
- ACSM2A | c.682C>A p.P228T (on ENST00000219054; = p.P149T on NM_001308169.2) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54590450, COSV99525475; called by muse, mutect2, varscan2
- AGXT | c.1012T>G p.Y338D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100280194; called by muse, mutect2
- ATM | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53735105; called by muse, mutect2, varscan2
- BCAT1 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53910295; called by muse, mutect2, varscan2
- C2CD3 | c.1404G>C p.E468D | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100487058; called by muse, mutect2, varscan2
- C8orf34 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100447057; called by muse, mutect2, varscan2
- DCANP1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.157); catalogued as rs750575659, COSV101538239; called by muse, mutect2, varscan2
- DGKH | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.396); catalogued as COSV99819221; called by muse, mutect2, varscan2
- DMD | c.6602A>T p.D2201V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV100628393; called by muse, mutect2, varscan2
- DNAH3 | c.10204G>A p.A3402T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs765445250, COSV54524923; called by muse, mutect2, varscan2
- DOP1B | c.5551A>G p.S1851G | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV101215641; called by muse, mutect2, varscan2
- EIF3B | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV100703786; called by muse, mutect2, varscan2
- FILIP1L | c.2320T>A p.Y774N (on ENST00000354552 / NM_182909.3; = p.Y534N on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV100497151; called by muse, mutect2
- FYTTD1 | c.794G>T p.S265I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV99611739; called by muse, mutect2, varscan2
- GABRG1 | c.792dup p.D265* | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | catalogued as rs772301203; called by mutect2, varscan2
- HCN2 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as COSV99242064; called by muse, mutect2, varscan2
- HECW1 | c.4663C>T p.R1555W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754041766, COSV67823226; called by muse, mutect2, varscan2
- HSPA12A | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201237054; called by muse, mutect2, varscan2
- HTT | c.3327G>A p.W1109* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100751020, COSV61871124; called by muse, mutect2, varscan2
- ITGAV | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99655340; called by muse, mutect2, varscan2
- JAKMIP2 | c.2205del p.F735Lfs*5 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as COSV54614389; called by mutect2, pindel, varscan2
- KL | c.2170G>A p.G724R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101199155; called by muse, mutect2, varscan2
- KLHDC7A | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs543307586, COSV101272826, COSV68769139; called by muse, mutect2, varscan2
- KMT2C | c.11314T>A p.S3772T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100074375; called by muse, mutect2, varscan2
- LATS1 | c.2983C>G p.R995G | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53587210, COSV99486386; called by muse, mutect2
- LIG3 | c.2932G>A p.V978M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs755498333, COSV99252904; called by muse, mutect2, varscan2
- LIPH | c.735A>T p.K245N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99956150; called by muse, mutect2, varscan2
- LRRTM4 | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.632); catalogued as COSV101297639; called by muse, mutect2, varscan2
- MCOLN2 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV99394083; called by muse, mutect2, varscan2
- MEN1 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV53641778, COSV53647085; called by muse, mutect2, varscan2
- OR1L8 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs748254512, COSV59186491; called by muse, mutect2, varscan2
- PCDHGA5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53974388; called by muse, mutect2, varscan2
- PDS5A | c.1485T>A p.D495E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100337478; called by muse, mutect2
- PPARGC1A | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99338253; called by muse, mutect2, varscan2
- PTPRB | c.5039C>T p.S1680F | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV99039196, COSV99718045; called by muse, mutect2
- PYHIN1 | c.339T>A p.Y113* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100932380; called by muse, mutect2, varscan2
- RAB37 | c.331G>T p.D111Y (on ENST00000392613 / NM_001006638.3; = p.D104Y on NM_175738.5) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100463261; called by muse, mutect2, varscan2
- REV3L | c.7475G>A p.R2492H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs578253914, COSV100725435; called by muse, mutect2
- RHOJ | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57459577; called by muse, mutect2
- RUBCN | c.2689G>T p.E897* | Nonsense Mutation (SNP) | VAF 8/219 reads (4%) | catalogued as COSV56369463; called by muse, mutect2
- SCAPER | c.2282T>A p.I761N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100238955; called by muse, mutect2, varscan2
- SRRM2 | c.3820G>T p.V1274L | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1368854247, COSV100071152; called by muse, mutect2, varscan2
- TCHH | c.3069dup p.D1024Rfs*194 | Frame Shift Ins (INS) | VAF 16/93 reads (17%) | catalogued as rs1298090051; called by mutect2, pindel, varscan2
- TGFBR3 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 51/124 reads (41%) | catalogued as COSV99283382; called by muse, mutect2, varscan2
- THBS4 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs779865957, COSV63468107; called by muse, mutect2, varscan2
- TOLLIP | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV99719632; called by muse, mutect2, varscan2
- TTN | c.51611C>T p.T17204M (on ENST00000591111; = p.T9780M on NM_003319.4) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | PolyPhen possibly damaging (0.584); catalogued as rs371571153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR49 | c.179G>A p.G60D (on ENST00000308378 / NM_001366158.1; = p.G401D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778938192, COSV100393348; called by muse, mutect2, varscan2
- ZC2HC1A | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55671409, COSV99804262; called by muse, mutect2, varscan2
- ZFYVE16 | c.2663T>C p.L888S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100566545; called by muse, mutect2, varscan2
- ZNF32 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV100986506, COSV65641849; called by muse, mutect2
- ZNF473 | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99568986; called by muse, mutect2, varscan2
- ZNF681 | c.1857A>C p.K619N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV101267525; called by muse, mutect2
- ZNF835 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV101606383; called by muse, mutect2, varscan2
- MUC20 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.282); called by muse, mutect2
- PSEN1 | c.1283del p.F428Sfs*33 | Frame Shift Del (DEL) | VAF 17/191 reads (9%) | called by mutect2, pindel
- RNF38 | c.1248del p.V417* | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- ZNF804B | c.1236dup p.S413Ifs*4 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- FAM114A2 | c.714G>T p.G238= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100697752; called by muse, mutect2, varscan2
- GRM1 | c.270C>T p.N90= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1403988868, COSV99267626; called by muse, mutect2, varscan2
- GRM8 | c.639G>T p.L213= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100284568; called by muse, mutect2, varscan2
- IMPG1 | c.2127G>A p.E709= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100774826; called by muse, mutect2, varscan2
- MYH2 | c.5469C>G p.A1823= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV99820567; called by muse, mutect2, varscan2
- PCDHGB2 | c.705C>T p.A235= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99542477; called by muse, mutect2, varscan2
- PCSK2 | c.1029C>T p.Y343= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1441737223, COSV52740544; called by muse, mutect2, varscan2
- PDIA6 | c.984A>G p.K328= | Silent (SNP) | VAF 130/228 reads (57%) | catalogued as COSV99694773; called by muse, mutect2, varscan2
- PKM | c.957A>G p.R319= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100065035, COSV100065039; called by muse, mutect2, varscan2
- RYR1 | c.24C>T p.D8= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as COSV100616377; called by muse, mutect2, varscan2
- SLC6A13 | c.1203G>A p.A401= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs140923338; called by muse, mutect2, varscan2
- ZNF280A | c.1287C>G p.L429= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV100131135; called by muse, mutect2, varscan2
- PDE4D | c.455+124743C>T | Intron (SNP) | VAF 17/161 reads (11%) | catalogued as COSV100507774; called by muse, mutect2, varscan2
